Somatic mutation profile of tumor specimen 0DQZ4I from CCDI case PBCFVW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain stem; Age at diagnosis: 12.2 years (4,465 days).
Specimen 0DQZ4I: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f501f384-c7a4-4523-b7ad-bfe487073c93.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQZ3M (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c7cf98f2-4dab-4819-a2be-f7e02e4c6aab

The open-access MAF lists 7 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 3, Nonsense Mutation 3, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FAM186A | c.7006C>T p.R2336* | Nonsense Mutation (SNP) | VAF 29/217 reads (13%) | catalogued as rs764641446; called by mutect2, varscan2
- LAMC3 | c.2850C>A p.C950* | Nonsense Mutation (SNP) | VAF 158/283 reads (56%) | catalogued as COSV100736129; called by muse, mutect2, varscan2
- MRGPRG | c.443G>A p.R148H | Missense Mutation (SNP) | VAF 32/247 reads (13%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs902099041; called by muse, mutect2, varscan2
- KCNE3 | c.80G>A p.S27N | Missense Mutation (SNP) | VAF 12/349 reads (3%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2
- PADI6 | c.1213A>C p.T405P | Missense Mutation (SNP) | VAF 11/354 reads (3%) | SIFT tolerated (1); PolyPhen possibly damaging (0.9); called by muse, mutect2
- SELL | c.259G>T p.E87* (on ENST00000650983; = p.E74* on NM_000655.5) | Nonsense Mutation (SNP) | VAF 196/408 reads (48%) | called by muse, mutect2, varscan2
- OVOL1 | c.609C>T p.Y203= | Silent (SNP) | VAF 37/297 reads (12%) | catalogued as rs767600762, COSV60120541; called by muse, mutect2, varscan2
